Somatic mutation profile of tumor specimen TCGA-FG-7634-01A (aliquot TCGA-FG-7634-01A-11D-2086-08) from TCGA case TCGA-FG-7634, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 28.7 years (10,476 days).
Specimen TCGA-FG-7634-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af097a15-d9f9-4f1b-a202-7378130c7832.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-7634-10A (Blood Derived Normal), aliquot TCGA-FG-7634-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ef5102c-5116-43c4-86b3-c7a65b036a18

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Del 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 50/120 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CDK12 | c.3023G>A p.R1008Q | Missense Mutation (SNP) | VAF 71/258 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70999629; called by muse, mutect2, varscan2
- CIC | c.4412G>A p.R1471Q | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV50550046; called by muse, mutect2, varscan2
- EPHX2 | c.1534C>A p.P512T | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs775866891, CM145500, COSV66844130; called by muse, mutect2, varscan2
- GLB1L | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.226); catalogued as rs1312328284, COSV55475694; called by muse, mutect2, varscan2
- LILRA2 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 68/116 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.72); catalogued as rs559006483, COSV52189167; called by muse, mutect2, varscan2
- OR10J5 | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV58385091; called by muse, mutect2, varscan2
- PCDH7 | c.2809G>C p.D937H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV62337194; called by muse, mutect2, varscan2
- PDE6C | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as rs143673530; called by muse, mutect2
- PIK3CA | c.32G>C p.W11S | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55873743, COSV55891755; called by muse, mutect2, varscan2
- SLFN11 | c.2307G>A p.W769* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as COSV57697891; called by muse, mutect2, varscan2
- ZNF148 | c.1183del p.I395Lfs*7 | Frame Shift Del (DEL) | VAF 42/75 reads (56%) | called by mutect2, pindel, varscan2
- MYG1 | c.21C>G p.R7= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99670449; called by muse, mutect2
- PCDH9 | c.2415A>G p.Q805= | Silent (SNP) | VAF 18/254 reads (7%) | catalogued as COSV60533934; called by muse, mutect2
- ZNF347 | c.81C>T p.P27= | Silent (SNP) | VAF 58/110 reads (53%) | catalogued as rs201753900, COSV61967805; called by muse, mutect2, varscan2
- IQSEC3 | c.3114+143A>T | Intron (SNP) | VAF 64/164 reads (39%) | catalogued as COSV100407279; called by muse, mutect2, varscan2
